Somatic mutation profile of tumor specimen TCGA-DD-A116-01A (aliquot TCGA-DD-A116-01A-11D-A12Z-10) from TCGA case TCGA-DD-A116, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.3 years (24,934 days).
Specimen TCGA-DD-A116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65f175e1-a2f3-4e99-94bb-af11238134ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A116-10A (Blood Derived Normal), aliquot TCGA-DD-A116-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37cabbf2-50d6-4cb7-8fff-1454586da0c0

The open-access MAF lists 126 somatic variants for this specimen: 94 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 29, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 1, Splice Region 1, Nonstop Mutation 1, 3'Flank 1, 3'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 62/197 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV55120874; called by muse, mutect2, varscan2
- ACVRL1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66360620; called by muse, mutect2, varscan2
- ADAT1 | c.1303A>G p.K435E | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57187648; called by muse, mutect2, varscan2
- ADCK1 | c.542A>G p.K181R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV53083446; called by muse, mutect2, varscan2
- ADGRF1 | c.2490G>C p.Q830H | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753315090, COSV51946720; called by muse, mutect2, varscan2
- AGO4 | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 136/247 reads (55%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV64617959; called by muse, mutect2, varscan2
- ALOX15B | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs768290223, COSV66479836; called by muse, mutect2, varscan2
- AMACR | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1561045920, COSV59462048; called by muse, mutect2, varscan2
- ANKRD12 | c.3137A>T p.K1046I | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50836359; called by muse, mutect2, varscan2
- ARAP2 | c.925A>T p.N309Y | Missense Mutation (SNP) | VAF 251/354 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV58289717; called by muse, mutect2, varscan2
- ARID3C | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV52408235; called by muse, mutect2, varscan2
- ATRNL1 | c.3568T>C p.S1190P | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58101684; called by muse, mutect2, varscan2
- BAHD1 | c.2056T>A p.L686M | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as COSV69084320; called by muse, mutect2, varscan2
- BDH1 | c.1032A>C p.*344Cext*26 | Nonstop Mutation (SNP) | VAF 48/141 reads (34%) | catalogued as COSV64019202; called by muse, mutect2, varscan2
- C14orf39 | c.1387G>C p.V463L | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV58783655; called by muse, mutect2, varscan2
- CACNA1E | c.764A>T p.N255I | Missense Mutation (SNP) | VAF 175/503 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV62407485; called by muse, mutect2, varscan2
- CDH7 | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV59890110; called by muse, varscan2
- CELSR2 | c.2918T>C p.I973T | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.932); catalogued as COSV54776211; called by muse, mutect2, varscan2
- CFAP206 | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51535590; called by muse, mutect2, varscan2
- CGN | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV54972054; called by muse, mutect2, varscan2
- COL6A6 | c.1850A>G p.K617R | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV62031831; called by muse, mutect2, varscan2
- CSMD3 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 81/378 reads (21%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.935); catalogued as rs557572936, COSV52252824; called by muse, mutect2, varscan2
- DNAH5 | c.9496A>G p.R3166G | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54240415; called by muse, mutect2, varscan2
- DOCK2 | c.1907A>T p.K636M | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV56973921; called by muse, mutect2, varscan2
- DSP | c.7897A>G p.I2633V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.416); catalogued as rs1305316361, COSV65794251; called by muse, mutect2
- EPB41L3 | c.911A>T p.K304M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV59461637; called by muse, mutect2, varscan2
- ERC1 | c.3013T>A p.S1005T (on ENST00000360905 / NM_178040.4; = p.S977T on NM_178039.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV61697494; called by muse, mutect2, varscan2
- ERCC8 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54017095; called by muse, mutect2, varscan2
- FMO1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.099); catalogued as rs765073901, COSV61445185; called by muse, mutect2, varscan2
- FOXN1 | c.122G>T p.S41I | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV56883069; called by muse, mutect2, varscan2
- FREM2 | c.3997G>C p.D1333H | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54845009; called by muse, mutect2, varscan2
- FZR1 | c.575T>G p.L192R | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58052767; called by muse, mutect2, varscan2
- GIT2 | c.1507A>G p.R503G (on ENST00000355312 / NM_057169.5; = p.R455G on NM_014776.5) | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV58083316; called by muse, mutect2, varscan2
- HECW2 | c.4375A>G p.S1459G | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV53667813; called by muse, mutect2, varscan2
- HGSNAT | c.857T>A p.V286E | Missense Mutation (SNP) | VAF 106/187 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52818026, COSV99925643; called by muse, mutect2, varscan2
- HMGXB4 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV53335125; called by muse, mutect2, varscan2
- INTS7 | c.555A>G p.Q185= | Splice Region (SNP) | VAF 39/576 reads (7%) | catalogued as COSV65344886; called by muse, mutect2
- KIF4B | c.2823C>G p.S941R | Missense Mutation (SNP) | VAF 79/440 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs754074497, COSV70530516; called by muse, mutect2, varscan2
- KNDC1 | c.4222G>T p.G1408C | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV58842316; called by muse, mutect2, varscan2
- KRT75 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 74/170 reads (44%) | catalogued as COSV52874090; called by muse, varscan2
- KRTAP13-2 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV67762176; called by muse, mutect2, varscan2
- LEO1 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV55176653; called by muse, mutect2, varscan2
- LRRC18 | c.58A>G p.N20D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV53284823; called by muse, mutect2, varscan2
- LTBP3 | c.952A>C p.K318Q | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV57242593; called by muse, mutect2, varscan2
- MAP4K2 | c.1405C>A p.H469N | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV53646184; called by muse, mutect2, varscan2
- MRPL10 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV51620667; called by muse, mutect2, varscan2
- MUC16 | c.40258C>A p.H13420N | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.871); catalogued as rs1203893129, COSV66694797; called by muse, mutect2, varscan2
- MUC16 | c.4702A>G p.T1568A | Missense Mutation (SNP) | VAF 142/374 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV67480351; called by muse, mutect2, varscan2
- MYH6 | c.1911A>T p.K637N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62452832; called by muse, mutect2, varscan2
- MYH7 | c.5654C>T p.A1885V | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV62521650; called by muse, mutect2, varscan2
- MYO1G | c.2914C>A p.L972M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV51855996; called by muse, mutect2, varscan2
- NBPF15 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1380003639, COSV64993469; called by mutect2, varscan2
- NEU1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); catalogued as COSV57668352; called by muse, mutect2, varscan2
- NOS1 | c.2377A>G p.M793V | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs753615929, COSV57617322; called by muse, mutect2, varscan2
- NPC1 | c.1835A>G p.E612G | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1484115935, COSV52581354; called by muse, mutect2, varscan2
- PDK3 | c.1016A>C p.Q339P | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV64793936; called by muse, mutect2
- PHLDB3 | c.1634G>T p.R545L | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52670957; called by muse, mutect2, varscan2
- PIGR | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV62904624; called by muse, mutect2, varscan2
- PLP1 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 126/165 reads (76%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100393486, COSV58277785; called by muse, mutect2, varscan2
- PPP1CC | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 36/325 reads (11%) | catalogued as COSV58584402; called by muse, mutect2, varscan2
- PRB4 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 160/434 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV54398503; called by muse, mutect2, varscan2
- QRFPR | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751553958, COSV57677217; called by muse, varscan2
- RAB3GAP2 | c.2018G>C p.R673T | Missense Mutation (SNP) | VAF 106/349 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.109); catalogued as COSV62785794; called by muse, mutect2, varscan2
- RAPGEF1 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV64700998; called by muse, mutect2, varscan2
- RBSN | c.2301G>T p.E767D | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV53794600; called by muse, mutect2, varscan2
- RFX7 | c.1960T>G p.S654A (on ENST00000559447 / NM_001368074.1; = p.S751A on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57966595; called by muse, mutect2, varscan2
- RRP1B | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61479723; called by muse, mutect2, varscan2
- SESN3 | c.688A>G p.N230D | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.046); catalogued as COSV53586303; called by muse, mutect2
- SLC9A3 | c.2501T>A p.M834K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as COSV53803254; called by muse, varscan2
- SMC3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.052); catalogued as COSV62421253; called by muse, mutect2, varscan2
- SMG5 | c.2829-1G>T p.X943_splice | Splice Site (SNP) | VAF 29/54 reads (54%) | catalogued as COSV52746040; called by muse, mutect2, varscan2
- SMOX | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53866642; called by muse, mutect2, varscan2
- SPHK1 | c.991C>G p.P331A (on ENST00000392496 / NM_001355139.2; = p.P345A on NM_021972.4) | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1360711567, COSV60065655; called by muse, mutect2, varscan2
- SPINDOC | c.158G>C p.R53T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs779268016, COSV53693283; called by muse, mutect2, varscan2
- TBX10 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); catalogued as COSV56876115; called by muse, mutect2, varscan2
- TEP1 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV52996417; called by muse, mutect2, varscan2
- TGIF2LX | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 200/254 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52214676; called by muse, mutect2, varscan2
- TNPO1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | catalogued as COSV61522997; called by muse, mutect2, varscan2
- TRPA1 | c.1558C>G p.H520D | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51568369; called by muse, mutect2, varscan2
- TRPM6 | c.2918T>C p.M973T | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs142068228; called by muse, mutect2, varscan2
- TVP23C | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs17850827, COSV56671557; called by muse, mutect2, varscan2
- WWC1 | c.2948G>A p.R983H | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs139653620, COSV99514164; called by muse, varscan2
- ZDHHC19 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV56349445; called by muse, mutect2, varscan2
- ZFHX4 | c.8084G>T p.R2695L | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51476733, COSV51492320; called by muse, mutect2, varscan2
- ZFP64 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53802072; called by muse, mutect2, varscan2
- ZNF414 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55322333; called by muse, mutect2, varscan2
- ZNF536 | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140147461; called by muse, mutect2, varscan2
- BIN1 | c.752del p.N251Tfs*6 (on ENST00000316724 / NM_001320642.1; = p.N220Tfs*6 on NM_004305.4) | Frame Shift Del (DEL) | VAF 44/125 reads (35%) | called by mutect2, varscan2
- CCNB1IP1 | c.717dup p.A240Cfs*8 | Frame Shift Ins (INS) | VAF 68/235 reads (29%) | called by mutect2, varscan2
- FCGBP | c.1892C>G p.P631R | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- MAP2K4 | c.772_773del p.I258Cfs*9 | Frame Shift Del (DEL) | VAF 30/57 reads (53%) | called by mutect2, varscan2
- NUMA1 | c.2329_2338del p.A777Lfs*31 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, varscan2
- ZNF790 | c.1377_1380del p.L460Mfs*192 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | called by mutect2, varscan2
- ACTC1 | c.609C>T p.V203= | Silent (SNP) | VAF 51/149 reads (34%) | catalogued as rs1055408313, COSV51760302; called by muse, mutect2, varscan2
- ADAD1 | c.87G>A p.A29= | Silent (SNP) | VAF 77/116 reads (66%) | catalogued as rs920358064, COSV56643988; called by muse, mutect2, varscan2
- ARAP3 | c.4509G>T p.L1503= | Silent (SNP) | VAF 78/190 reads (41%) | catalogued as rs766946715, COSV53352701; called by muse, mutect2, varscan2
- C1QTNF2 | c.420A>G p.P140= (on ENST00000393975; = p.P95= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV67433054; called by muse, mutect2, varscan2
- C1S | c.1617G>A p.V539= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs868987736, COSV61071596; called by muse, mutect2, varscan2
- CACNA1B | c.2037C>G p.V679= | Silent (SNP) | VAF 128/190 reads (67%) | catalogued as COSV53138219; called by muse, mutect2, varscan2
- DCST2 | c.828G>T p.R276= | Silent (SNP) | VAF 84/222 reads (38%) | catalogued as COSV55053263; called by muse, mutect2, varscan2
- EIF4G1 | c.4266G>A p.V1422= (on ENST00000346169 / NM_198241.3; = p.V1227= on NM_004953.5) | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV59992468; called by muse, mutect2, varscan2
- EPPK1 | c.2064C>A p.V688= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as COSV73261992; called by muse, mutect2, varscan2
- FLT4 | c.2379C>G p.L793= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as COSV56116417; called by muse, mutect2, varscan2
- HIRA | c.945T>C p.C315= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV54277556; called by muse, mutect2, varscan2
- HYAL4 | c.1380T>A p.P460= | Silent (SNP) | VAF 100/270 reads (37%) | catalogued as COSV56139521; called by muse, mutect2, varscan2
- IGLV1-44 | c.342C>T p.S114= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as rs556021668; called by muse, mutect2, varscan2
- LILRB1 | c.1989G>A p.V663= (on ENST00000427581; = p.V612= on NM_006669.6) | Silent (SNP) | VAF 83/231 reads (36%) | catalogued as COSV61116545; called by muse, mutect2, varscan2
- MCPH1 | c.546G>A p.E182= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV60916923; called by muse, mutect2, varscan2
- MYDGF | c.462A>T p.A154= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs745874684, COSV53561223; called by muse, mutect2, varscan2
- OR4D9 | c.171G>A p.T57= | Silent (SNP) | VAF 17/451 reads (4%) | catalogued as rs1451512271, COSV61435763; called by muse, mutect2
- PREX2 | c.453G>T p.L151= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as rs747847529, COSV55787505; called by muse, mutect2, varscan2
- SEMA3E | c.621G>A p.G207= | Silent (SNP) | VAF 65/191 reads (34%) | catalogued as COSV57100370; called by muse, mutect2, varscan2
- SLC45A4 | c.399C>T p.G133= (on ENST00000517878 / NM_001286646.2; = p.G82= on NM_001080431.2) | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs763316622, COSV50133187; called by muse, mutect2, varscan2
- SLX4 | c.990G>T p.V330= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as COSV53566402; called by muse, mutect2, varscan2
- TRAM1L1 | c.33C>T p.P11= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as rs768931259, COSV60292770; called by muse, mutect2, varscan2
- USP36 | c.2181C>T p.P727= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as rs372776119; called by muse, mutect2, varscan2
- USP47 | c.1002T>C p.Y334= (on ENST00000399455 / NM_001372095.1; = p.Y246= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 83/212 reads (39%) | catalogued as rs748072362, COSV60466021; called by muse, mutect2, varscan2
- VIM | c.1248A>T p.P416= | Silent (SNP) | VAF 141/355 reads (40%) | catalogued as COSV56406866; called by muse, mutect2, varscan2
- VTN | c.1413C>G p.G471= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV52647624; called by muse, mutect2, varscan2
- YTHDF3 | c.411G>A p.G137= | Silent (SNP) | VAF 163/711 reads (23%) | catalogued as COSV72773047; called by muse, mutect2, varscan2
- ZHX1 | c.630A>G p.K210= | Silent (SNP) | VAF 116/557 reads (21%) | catalogued as COSV52877938; called by muse, mutect2, varscan2
- ZNF687 | c.1240C>T p.L414= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV55019788; called by muse, mutect2, varscan2
- POM121 | chr7:72949450 del GATGCCAGCCGC | 3'Flank (DEL) | VAF 34/134 reads (25%) | called by mutect2, varscan2*
- SYTL2 | c.1459+2042T>C | Intron (SNP) | VAF 147/420 reads (35%) | catalogued as COSV60361318; called by muse, mutect2, varscan2
- TRIM14 | c.*129C>T | 3'UTR (SNP) | VAF 53/80 reads (66%) | catalogued as rs746193952; called by muse, mutect2, varscan2
